MMRF case MMRF_1359 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3eee1d4b-bb90-42c1-84ce-e0de2d219fa2

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 1,170 days (3.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.8 years (20,033 days); ISS stage: III; Days to last known disease status: 1,170 days (3.2 years); Days to last follow up: 1,170 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 694 days (1.9 years); Days to treatment end: 862 days (2.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 694 days (1.9 years); Days to treatment end: 876 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 882 days (2.4 years); Days to treatment end: 1,106 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,123 days (3.1 years); Days to treatment end: 1,162 days (3.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,170.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 512 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Immunoglobulin G 48.9 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.02 g/L; Beta 2 Microglobulin 8.27 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 12.6 ×10⁹/L; Absolute Neutrophil 7.99 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 9 g/dL; Glucose 4.62 mmol/L.
- Day 63 (ECOG 0): M Protein 0.3 g/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.6 µg/mL; Hemoglobin 5.39 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 4.9 mmol/L.
- Day 133 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.67 µg/mL; Hemoglobin 5.64 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 247: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.31 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 329 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 5.46 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 5.45 mmol/L.
- Day 406: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 540: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 6.53 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 2.23 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 56.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.01 g/L; Beta 2 Microglobulin 2.59 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.89 mmol/L.
- Day 718 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 27.9 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.01 g/L; Beta 2 Microglobulin 3.73 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 37 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.93 mmol/L; Albumin 32 g/L; Total Protein 7.3 g/dL; Glucose 5.34 mmol/L.
- Day 802 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 8.59 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.72 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 67 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 912 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 3.94 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.36 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 4.03 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 983: Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 6.33 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.42 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 18.4 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,081 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 319 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 50.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 8.2 µg/mL; Hemoglobin 4.77 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 86 ×10⁹/L.
- Day 1,159 (ECOG 0): M Protein 6.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 79.2 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 35.7 µg/mL; Hemoglobin 4.28 mmol/L; Leukocytes 15.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 1 ×10⁹/L; Creatinine 369 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.38 mmol/L; Albumin 18 g/L; Total Protein 11.3 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -6: Weight: 96 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1359_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1359_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
